Somatic mutation profile of tumor specimen TCGA-12-3648-01A (aliquot TCGA-12-3648-01A-01W-0922-08) from TCGA case TCGA-12-3648, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.5 years (22,463 days).
Specimen TCGA-12-3648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76259991-18f8-43ab-9b28-e3cd9e7bb611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3648-10A (Blood Derived Normal), aliquot TCGA-12-3648-10A-01W-0922-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82414dc1-c28d-40da-9cdb-71f6c19a5044

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 18, Frame Shift Del 2, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS1B | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1374120858, COSV101612657; called by muse, varscan2
- B3GNTL1 | c.252dup p.H85Afs*7 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | catalogued as rs755556988; called by pindel, varscan2
- CEBPD | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52390057; called by mutect2, varscan2
- CMTM8 | c.221T>C p.M74T | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100282468; called by muse, mutect2, varscan2
- CRLF2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.04); catalogued as COSV101053662; called by muse, mutect2, varscan2
- DBH | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101256955; called by muse, mutect2, varscan2
- DIS3 | c.1999_2000del p.M667Vfs*13 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | catalogued as rs1428278025; called by mutect2, pindel, varscan2
- DMKN | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.109); catalogued as COSV100303463; called by muse, mutect2, varscan2
- EFHB | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as COSV99859395; called by muse, mutect2, varscan2
- EGF | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 283/598 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV99490717; called by muse, mutect2, varscan2
- EPHB1 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 161/320 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs373797543, COSV67655662, COSV67667897; called by muse, mutect2, varscan2
- ESF1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99176318; called by muse, mutect2, varscan2
- GOT1 | c.987C>A p.D329E | Missense Mutation (SNP) | VAF 84/102 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100981698; called by muse, mutect2, varscan2
- HEPH | c.3052C>T p.R1018W (on ENST00000343002; = p.R751W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 273/649 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770936800, COSV57965178; called by muse, mutect2, varscan2
- HHIP | c.1514T>G p.L505W | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99666983; called by muse, mutect2, varscan2
- ISX | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 103/241 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs373068000; called by muse, mutect2, varscan2
- LAMB4 | c.4247C>T p.T1416M | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs775934990, COSV99223361, COSV99225818; called by muse, mutect2, varscan2
- LRRC18 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs377713029, COSV53284256; called by muse, mutect2, varscan2
- MSL2 | c.836C>G p.T279S | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.971); catalogued as COSV99386832; called by muse, mutect2, varscan2
- NETO1 | c.130T>A p.W44R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100198483; called by muse, mutect2, varscan2
- NLRP3 | c.269C>G p.P90R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as rs145774400, COSV100275722; called by muse, mutect2, varscan2
- PCDHB3 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.069); catalogued as rs558026324, COSV50571674; called by muse, mutect2, varscan2
- PRAMEF4 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 196/256 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs756061364, COSV99339407, COSV99339676; called by mutect2, varscan2
- PXK | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 382/894 reads (43%) | catalogued as rs780169488, COSV57095886; called by muse, mutect2, varscan2
- RBM12 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 126/461 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100467320; called by muse, mutect2, varscan2
- RTL6 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV57979263; called by muse, mutect2, varscan2
- SALL4 | c.1980G>C p.E660D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1486806662, COSV53849979, COSV99409384; called by muse, mutect2, varscan2
- SBF1 | c.5312G>A p.R1771H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as rs559286048, COSV53296467; called by muse, mutect2, varscan2
- SLC6A15 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs778232072, COSV99880511; called by muse, mutect2, varscan2
- SLCO2A1 | c.1856T>C p.L619P | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100188838; called by muse, mutect2, varscan2
- TPO | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs150812908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE3A | c.99A>G p.I33M | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99217013; called by muse, mutect2, varscan2
- VPS18 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs367634085; called by muse, mutect2, varscan2
- VWF | c.4735G>T p.G1579W | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011512, COSV54615661; called by muse, mutect2
- WDR62 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV99543472; called by muse, mutect2, varscan2
- CFH | c.3694_*1del | Frame Shift Del (DEL) | VAF 61/144 reads (42%) | called by mutect2, pindel, varscan2
- CAMKV | c.885C>T p.N295= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV99615340; called by muse, mutect2, varscan2
- DSC3 | c.2448C>T p.Y816= | Silent (SNP) | VAF 91/217 reads (42%) | catalogued as COSV100844569; called by muse, mutect2, varscan2
- ENG | c.789C>A p.I263= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as CD040893, CD040894, COSV100785265; called by muse, mutect2
- GARS1 | c.471G>A p.L157= | Silent (SNP) | VAF 66/252 reads (26%) | catalogued as rs367915362, COSV101220050; called by muse, varscan2
- GTPBP3 | c.486G>A p.A162= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs781243432, COSV99344297; called by muse, mutect2, varscan2
- HEXD | c.975T>A p.L325= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100027667; called by muse, mutect2, varscan2
- HTR2C | c.501G>A p.S167= | Silent (SNP) | VAF 180/417 reads (43%) | catalogued as rs782120660, COSV52211048; called by muse, varscan2
- MMRN1 | c.3420G>A p.P1140= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs369702396; called by muse, mutect2, varscan2
- NOS1 | c.1755C>T p.S585= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as rs756897335, COSV100500353; called by muse, mutect2, varscan2
- OR8D1 | c.216C>T p.C72= | Silent (SNP) | VAF 116/252 reads (46%) | catalogued as COSV100766606; called by muse, mutect2, varscan2
- OVCH1 | c.693C>T p.D231= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs372417527; called by muse, mutect2, varscan2
- PCDHA12 | c.288C>T p.C96= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs781811926, COSV56501287; called by muse, mutect2
- PNLIPRP2 | c.219G>A p.T73= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs370558038; called by muse, mutect2, varscan2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs147089589; called by muse, mutect2, varscan2
- SATL1 | c.1026T>C p.F342= (on ENST00000395409; = p.F529= on NM_001012980.2) | Silent (SNP) | VAF 78/173 reads (45%) | catalogued as COSV100260752; called by muse, mutect2, varscan2
- SSTR2 | c.651C>T p.F217= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100192030; called by muse, mutect2, varscan2
- TSNARE1 | c.1524C>A p.A508= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100210178; called by muse, mutect2, varscan2
- ZNF280C | c.126C>T p.D42= | Silent (SNP) | VAF 198/483 reads (41%) | catalogued as rs1472421102, COSV63968936; called by muse, mutect2, varscan2
- RPLP2 | c.172+168T>A | Intron (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100337052; called by muse, mutect2, varscan2
